Surgical pathology report (de-identified scan), TCGA case TCGA-50-5933, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-50-5933-01A (Primary Tumor).

[page 1 of 2]
FINAL DIAGNOSIS:

PART 1: LUNG, LEFT, BIOPSY OF MASS –

ALVEOLATED LUNG FRAGMENTS POSITIVE FOR POORLY DIFFERENTIATED NON-SMALL CELL CARCINOMA.

PART 2: LUNG, LEFT, PNEUMONECTOMY –

- A. MODERATE TO POORLY DIFFERENTIATED ADENOCARCINOMA PREDOMINANTLY IN THE LEFT LOWER LOBE WITH CONTIGUOUS SPREAD TO THE LEFT UPPER LOBE (13.2 CM).
- B. THE NEOPLASM EXTENDS INTO BUT NOT THROUGH THE VISCERAL PLEURA (SLIDES 2E; see comment).
- C. MICROSCOPIC FOCUS OF TUMOR PRESENT IN ARTERIAL WALL AT VASCULAR MARGIN OF RESECTION (see comment).
- D. BRONCHIAL AND ALL OTHER VASCULAR MARGINS OF RESECTION ARE FREE OF NEOPLASM
- E. THE NON-NEOPLASTIC LUNG SHOWS CHANGES OF EMPHYSEMA.
- F. SIX PERIHILAR LYMPH NODES FREE OF NEOPLASM (0/6).
- G. PATHOLOGIC STAGE: PT4, N2, Mx; GRADE: G2 (see comment).

PART 3: BRONCHUS, LEFT MAINSTEM, EXCISION –

- A. SEGMENT OF BRONCHIAL WALL WITH NO SPECIFIC PATHOLOGIC CHANGE; NEGATIVE FOR NEOPLASM.
- B. NO SECONDARY CARCINOMA SEEN IN ONE LYMPH NODE EXAMINED (0/1).

PART 4: "ANTERIOR CHEST WALL", EXCISION –

- A. LUNG TISSUE WITH EMPHYSEMA.
- B. FIBROADIPOSE TISSUE FRAGMENTS WITH DENSE SCLEROSIS.
- C. NEGATIVE FOR NEOPLASM.

PART 5: "POSTERIOR CHEST WALL MARGIN", EXCISION –

- A. FIBROADIPOSE TISSUE WITH DENSE SCLEROSIS AND CHRONIC INFLAMMATION.
- B. NEGATIVE FOR NEOPLASM.

PART 6: "APICAL CHEST WALL MARGIN", EXCISION –

- A. FIBROADIPOSE TISSUE FRAGMENTS.
- B. NEGATIVE FOR NEOPLASM.

PART 7: "NODULE ON AORTIC ARCH", EXCISION –

MICROSCOPIC FOCUS OF METASTATIC CARCINOMA WITHIN THE VESSEL WALL (see comment).

PART 8: PORTION OF 6TH RIB, SIDE NOT SPECIFIED, EXCISION –

SEGMENT OF BONE WITH NO SPECIFIC PATHOLOGIC CHANGE.

PART 9: LYMPH NODES, SUBCARINAL, EXCISION –

NO SECONDARY CARCINOMA SEEN IN TEN LYMPH NODES EXAMINED (0/10).

PART 10: LYMPH NODE, PERIAORTIC, EXCISION –

SECONDARY CARCINOMA PRESENT IN ONE OF ONE LYMPH NODE EXAMINED WITH EXTRANODAL SPREAD (1/1).

PART 11: LYMPH NODE, AP WINDOW, EXCISION –

NO SECONDARY CARCINOMA SEEN IN ONE LYMPH NODE EXAMINED (0/1).

PART 12: LYMPH NODES, PARAESOPHAGEAL, EXCISION –

NO SECONDARY CARCINOMA PRESENT IN ONE LYMPH NODE EXAMINED (0/1).

PART 13: "NEO-PULMONARY ARTERY RESECTION MARGIN", EXCISION –

FRAGMENTS OF VESSEL WALL NEGATIVE FOR NEOPLASM.

PART 14: "PLEURAL MARGIN", EXCISION –

- A. CHRONIC FIBROUS AND FIBRINOUS PLEURITIS.
- NEGATIVE FOR NEOPLASM.

COMMENT:

In Part 2, special stain for elastin shows that the neoplasm extends into but not through the visceral pleura. A microscopic focus of neoplastic cells is present within the arterial wall at the vascular margin of resection. This neoplastic focus is seen on the frozen section and not on permanent section. Deeper levels of this margin are non-contributory. The frozen section slide was reviewed and our diagnosis regarding this margin remains unchanged. Given the positive vascular margin, the tumor clusters in part 7 (nodule on aortic arch) likely represents contiguous spread rather than a true metastasis. Hence, this lesion is best classified as Pt4 N2 Mx.

In Part 7, cytokeratin stain confirms the presence of neoplastic cells of epithelial origin within the vessel wall. has been ordered to confirm the epithelial origin of the neoplastic cells.

[page 2 of 2]
SYNOPTIC – PRIMARY LUNG TUMORS

A. Location: 4, 5

1. RUL

2. RML

3. RLL*

4. LLL

5. LUL

6. Bronchus intermedius

B. Procedure: 4

1. Wedge/Segmental

2. Lobectomy

3. Bilobectomy

4. Pneumonectomy

C. Size of tumor (maximum dimension): 13.2 cm.

D. Satellite nodules: 2

1. yes

2. No

D1. If yes, Where: N/A

1. Same lobe

2. Ipsilateral lobes

3. Central lobe

E. Type: 3

1. Invasive squamous carcinoma

2. Basaloid squamous carcinoma

3. Invasive adenocarcinoma

4. Bronchioloalveolar carcinoma, nonmucinous type

5. Bronchioloalveolar carcinoma, mucinous type

6. Large cell carcinoma

7. Clear cell carcinoma

8. Giant cell carcinoma

9. Sarcomatoid carcinoma

10. Blastoma

11. Fetal type adenocarcinoma

12. Small cell carcinoma

13. Carcinoid

14. Atypical carcinoid

15. Sarcoma

16. Adenosquamous carcinoma

17. Mixed non-small cell carcinoma, NOS

18. Carcinosarcoma

19. Other

F. Architectural grade: 3

1. well

2. moderate

3. poor/undifferentiated

G. Nuclear grade: 3

1. Low

2. Intermediate

3. High

H. Central vs. peripheral origin: 1

1. yes

2. no

I. Visceral pleural invasion through elastica: 1

1. yes

2. no

J. Parietal pleural invasion: 2

1. yes

2. no

K. Chest wall invasion (into skeletal muscle or soft tissue): 2

1. yes

2. no

L. Angiolymphatic invasion: 2

1. yes

2. no

M. Necrosis: 2

1. ≤50%

2. >50%

N. Surgical margins involved: 2

1. yes

2. no

O. Inflammatory (desmoplastic) reaction: 3

1. mild

2. moderate

3. severe

P. Hilar lymph node involvement (N1 nodes): 2

1. yes

2. no

Q. If hilar lymph nodes involved, number of positive lymph nodes: N/A

R. Total number of hilar lymph nodes examined: 6

S. Extracapsular spread of hilar lymph node metastases: N/A

1. yes

2. no

T. Mediastinal nodes involved: 1

1. yes

2. no

3. not applicable

U. Mediastinal node group(s) involved (N2 nodes): periaortic, side not specified

1. Level 4R

4. Level 7R

7. Level 4L

10. Level 7L

2. Level 5R

5. Level 9R

8. Level 5L

11. Level 9L

3. Level 6R

6. Level 10R

9. Level 6L

12. Level 10L

V. Number of positive mediastinal nodes: 1

W. Total number of mediastinal nodes examined: 12

X. Extracapsular spread of mediastinal lymph node metastases: 1

1. yes

2. No

Y. Underlying disease(s): 1/ # / # / #

1. Emphysema

2. Bronchiectasis

3. Tumorlets

4. Smokers bronchiolitis

5. Asthma

6. Parenchymal scar

7. Pneumoconiosis, NOS

8. Chronic interstitial pneumonia

Z. TNM Stage: T 4 N 2 M x

Source: NCI Genomic Data Commons file 578f3db4-d528-4069-8092-a1a3e0258f88 (TCGA-50-5933.68D471F3-43C0-44CF-97CE-003FF111C35C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).